Somatic mutation profile of tumor specimen TCGA-RW-A68F-01A (aliquot TCGA-RW-A68F-01A-11D-A35D-08) from TCGA case TCGA-RW-A68F, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 51.9 years (18,974 days).
Specimen TCGA-RW-A68F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d901aec-02c9-4f17-918c-e74c29ccbf8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A68F-10A (Blood Derived Normal), aliquot TCGA-RW-A68F-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0452373e-b8a8-4a0f-b21b-efaaa3bb6b10

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ECHDC2 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.639); catalogued as rs1304649312; called by muse, mutect2, varscan2
- MLXIP | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258623083, COSV59835972; called by muse, mutect2, varscan2
- RNF149 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); catalogued as COSV99766595; called by muse, mutect2, varscan2
- FZD8 | c.1468G>T p.V490F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.326); called by muse, mutect2
- IQSEC2 | c.3108G>T p.Q1036H (on ENST00000642864 / NM_001111125.3; = p.Q831H on NM_015075.2) | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- KIAA0319 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAB35 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STXBP3 | c.1193del p.N398Ifs*8 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- NUCKS1 | c.618A>G p.K206= | Silent (SNP) | VAF 99/274 reads (36%) | catalogued as rs770672139; called by muse, mutect2, varscan2
- PAK3 | c.1275C>G p.A425= (on ENST00000262836 / NM_001324328.2; = p.A410= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2
- RSF1 | c.3348A>G p.Q1116= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as rs779713699; called by muse, mutect2, varscan2
- RTL9 | c.1611C>T p.S537= | Silent (SNP) | VAF 87/222 reads (39%) | catalogued as COSV101511755; called by muse, mutect2, varscan2
- SLC35C1 | c.399C>G p.L133= | Silent (SNP) | VAF 30/42 reads (71%) | called by muse, mutect2, varscan2
- SLC38A4 | c.798G>A p.T266= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs780288309; called by muse, mutect2, varscan2
